Somatic mutation profile of tumor specimen ER-ACFR-TTP1-A (aliquot ER-ACFR-TTP1-A-1-0-D-A49A-34) from EXCEPTIONAL_RESPONDERS case ER-ACFR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell adenocarcinoma; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 53.1 years (19,382 days).
Specimen ER-ACFR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aee0247-17ec-416d-a0d6-25139ea00b36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ACFR-NT1-A (Solid Tissue Normal), aliquot ER-ACFR-NT1-A-1-0-D-A49A-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af33833c-22be-48a5-9288-6912fb36cdca

The open-access MAF lists 102 somatic variants for this specimen: 61 protein-altering or splice-affecting, 28 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 28, 3'UTR 6, Nonsense Mutation 5, Intron 4, Splice Site 3, 5'UTR 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 23/106 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASAP1 | c.530+1G>A p.X177_splice | Splice Site (SNP) | VAF 18/223 reads (8%) | catalogued as rs756640144, COSV63046611; called by muse, mutect2
- BAHCC1 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs537847945; called by muse, mutect2
- BAMBI | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs778969354, COSV65003137; called by muse, mutect2
- C10orf71 | c.2929G>T p.A977S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as rs1368452652; called by muse, mutect2, varscan2
- CNTN6 | c.2768G>A p.W923* | Nonsense Mutation (SNP) | VAF 24/239 reads (10%) | catalogued as rs770540542, COSV63184873; called by muse, mutect2, varscan2
- CT47B1 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760445575; called by muse, mutect2, varscan2
- GMCL1 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 44/794 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.414); catalogued as rs988065405; called by muse, mutect2
- GTPBP2 | c.1433C>G p.A478G | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV61077593; called by muse, mutect2
- HAUS4 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52828299; called by muse, mutect2
- KCNK15 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs1321444346; called by muse, mutect2, varscan2
- KIF5A | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV54051761; called by muse, mutect2
- KLF10 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as COSV99574678; called by muse, mutect2
- KLF15 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56180006; called by muse, mutect2
- MCPH1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs190026099, COSV100765970; called by muse, mutect2, varscan2
- MET | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 9/156 reads (6%) | catalogued as COSV59257638; called by muse, mutect2
- OTUD5 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs367931579, COSV50235804; called by muse, mutect2, varscan2
- POP1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as rs1240993528; called by muse, mutect2, varscan2
- RYR3 | c.12334G>C p.E4112Q (on ENST00000389232; = p.E4113Q on NM_001036.6) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as COSV66805637; called by muse, mutect2, varscan2
- TCHHL1 | c.1292G>C p.G431A | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.051); catalogued as COSV64286196; called by muse, mutect2
- ALKBH8 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2
- ASB4 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ATP5F1A | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- C6orf136 | c.352T>A p.Y118N | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- CBX8 | c.667G>C p.G223R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2
- CCDC102B | c.922A>C p.K308Q | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- CCDC168 | c.2438A>G p.D813G | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.222); called by muse, mutect2
- CCT3 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- CNKSR3 | c.1414C>G p.P472A | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.334); called by muse, mutect2
- CTSB | c.388_401del p.S130Gfs*17 | Frame Shift Del (DEL) | VAF 12/137 reads (9%) | called by mutect2, pindel
- DES | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DMXL2 | c.1151G>C p.G384A | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EEF2K | c.717C>A p.Y239* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- ERO1A | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 21/683 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2
- FYB1 | c.39T>A p.D13E | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- GRIN1 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2
- IL2RB | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM1A | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KIAA1549 | c.5816C>T p.S1939F (on ENST00000422774 / NM_001164665.2; = p.S1923F on NM_020910.3) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LENG9 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- MROH2B | c.2983-1G>C p.X995_splice | Splice Site (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- MTUS1 | c.3243G>C p.K1081N (on ENST00000262102 / NM_001363061.1; = p.K247N on NM_020749.4) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.437); called by muse, mutect2
- MUC16 | c.15595C>T p.Q5199* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- NELL1 | c.1642A>G p.K548E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLA2G4A | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLCB1 | c.1168-1G>C p.X390_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- PTGS2 | c.1099T>C p.F367L | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- RBAK | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RBL2 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RESF1 | c.855A>C p.R285S | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RUFY2 | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SERPINA9 | c.390G>C p.L130F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SUSD1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- TEX261 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- TG | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- USH2A | c.13843C>A p.L4615M | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WDR88 | c.1159A>G p.M387V | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- ZNF141 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZNF638 | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2
- ZNF781 | c.76A>G p.S26G | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZNF790 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ACSL6 | c.1530G>C p.V510= (on ENST00000379240; = p.V535= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- ANK2 | c.5253C>G p.V1751= | Silent (SNP) | VAF 17/323 reads (5%) | called by muse, mutect2
- ANKRD18A | c.1774A>C p.R592= | Silent (SNP) | VAF 18/195 reads (9%) | catalogued as COSV101294967, COSV68802209; called by muse, mutect2
- BRAF | c.1872T>G p.L624= (on ENST00000288602 / NM_001374244.1; = p.L584= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV56107641; called by muse, mutect2
- CENPJ | c.3204G>A p.K1068= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs774613587; called by mutect2, varscan2
- CGNL1 | c.2235C>T p.A745= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- EML4 | c.2010C>T p.I670= | Silent (SNP) | VAF 24/483 reads (5%) | catalogued as rs879264320; called by muse, mutect2
- GALNT13 | c.732T>G p.T244= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV101222246; called by muse, mutect2
- GRIN2B | c.1068C>T p.Y356= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as rs1201643405; called by muse, mutect2
- HTT | c.8172G>C p.L2724= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- MEF2A | c.397C>T p.L133= (on ENST00000557942 / NM_001319206.2; = p.L135= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- MYH9 | c.5349G>T p.L1783= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- NVL | c.2463C>G p.L821= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- OAS3 | c.348G>C p.L116= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as rs1284688157; called by muse, mutect2
- OR5D18 | c.720C>A p.S240= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- PCDHA3 | c.288C>T p.C96= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs529252017, COSV65367602, COSV65370261; called by muse, mutect2
- PCNX3 | c.4303C>T p.L1435= | Silent (SNP) | VAF 13/110 reads (12%) | called by mutect2, varscan2
- PITPNM2 | c.2184G>A p.P728= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1212985322; called by muse, mutect2
- POLR2A | c.3144G>A p.T1048= | Silent (SNP) | VAF 13/217 reads (6%) | catalogued as rs1049170821; called by muse, mutect2
- PRKDC | c.11775G>A p.L3925= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- PTPRH | c.141C>G p.S47= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99671554; called by muse, mutect2, varscan2
- SPHK2 | c.102T>A p.A34= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- TCERG1L | c.1044C>T p.V348= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- TMEM59 | c.898A>C p.R300= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2, varscan2
- TPT1 | c.249C>T p.F83= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- TRANK1 | c.7107C>T p.C2369= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ZNF146 | c.141C>T p.N47= | Silent (SNP) | VAF 41/327 reads (13%) | catalogued as rs747524610; called by muse, mutect2, varscan2
- ZNF543 | c.171G>A p.L57= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- APOL4 | c.91+1599C>T | Intron (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- B3GALT5 | c.*112C>T | 3'UTR (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100563529; called by muse, mutect2, varscan2
- CDC42BPA | c.4909+42G>A | Intron (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- CRYAA | c.189+529C>A | Intron (SNP) | VAF 14/77 reads (18%) | catalogued as rs751282271; called by muse, mutect2, varscan2
- FLRT2 | c.*2118T>G | 3'UTR (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- FLRT2 | c.*3658G>C | 3'UTR (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- IRS1 | c.-529G>A | 5'UTR (SNP) | VAF 18/176 reads (10%) | catalogued as rs1490600165; called by muse, mutect2
- MIR526A2 | n.51C>T | RNA (SNP) | VAF 14/89 reads (16%) | catalogued as rs1284549921; called by muse, mutect2, varscan2
- NPR3 | c.*4684G>T | 3'UTR (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- PRND | c.*3037T>A | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by mutect2, varscan2
- TM2D1 | c.-95G>A | 5'UTR (SNP) | VAF 12/309 reads (4%) | catalogued as rs1320513394; called by muse, mutect2
- TRMT12 | chr8:124453023 GAAATATGGTTAAGAATCACCAGTCTAT>AAATATGGTTAAGAATCACCAGTCTA | 3'UTR (DEL) | VAF 6/66 reads (9%) | called by pindel, varscan2*
- USP32P3 | n.3271+848C>T | Intron (SNP) | VAF 14/349 reads (4%) | called by muse, mutect2
